Somatic mutation profile of tumor specimen MMRF_1216_1_BM_CD138pos (aliquot MMRF_1216_1_BM_CD138pos_T1_KAS5U_L01731) from MMRF case MMRF_1216, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,218 days).
Specimen MMRF_1216_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85e80853-e7a0-4a1d-ac26-04ae07f122e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1216_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1216_1_PB_Whole_C2_KAS5U_L01732; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0e7fa6c-fea7-4e81-9c2e-a4eae3e42648

The open-access MAF lists 150 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 45, Missense Mutation 38, Intron 23, Silent 17, RNA 6, 5'UTR 6, 3'Flank 5, 5'Flank 4, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1477A>T | 3'UTR (SNP) | VAF 24/107 reads (22%) | catalogued as rs121913103, CM950477, CM990598, CM990599, COSV53412428; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 32/184 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AL121899.2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1420263769; called by muse, mutect2, varscan2
- BRAF | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.433); catalogued as rs1273585752, COSV56332603; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65425276; called by muse, mutect2, varscan2
- ERCC6L | c.71A>T p.Y24F | Missense Mutation (SNP) | VAF 95/501 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs1275963968; called by muse, mutect2, varscan2
- F8 | c.5507G>A p.W1836* | Nonsense Mutation (SNP) | VAF 162/440 reads (37%) | catalogued as CM062692; called by muse, mutect2, varscan2
- IGHV2-70 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs188731942; called by muse, varscan2
- IGLV3-25 | c.115A>C p.I39L | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs577514257; called by muse, varscan2
- MEMO1 | c.453T>A p.F151L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV54458014; called by muse, mutect2
- MIPOL1 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1014978109; called by muse, mutect2, varscan2
- MRPL30 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57666791; called by muse, mutect2
- PARS2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs559701159; called by muse, mutect2, varscan2
- PTPRN2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV67035239; called by muse, mutect2
- RIMS2 | c.3278C>T p.P1093L (on ENST00000666250 / NM_001348490.2; = p.P901L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99210639; called by muse, mutect2, varscan2
- SUSD3 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV64937173; called by muse, mutect2, varscan2
- WSCD1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 107/185 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs367964759; called by muse, mutect2, varscan2
- CCDC141 | c.1617A>C p.K539N | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CDH22 | c.2330G>A p.G777D | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.143); called by muse, mutect2
- DNAH10 | c.5554A>G p.T1852A (on ENST00000409039; = p.T1791A on NM_207437.3) | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DPEP3 | c.420G>T p.W140C | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EIF2B4 | c.996_1013+7del p.X332_splice (on ENST00000347454 / NM_001034116.2; = p.X331_splice on NM_015636.3) | Splice Site (DEL) | VAF 64/538 reads (12%) | called by mutect2, pindel
- FBN2 | c.4132T>A p.C1378S | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GUCY2F | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- HDLBP | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- IKZF2 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 188/389 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL19 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KLHL20 | c.586A>C p.N196H | Missense Mutation (SNP) | VAF 18/584 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.046); called by muse, mutect2
- LPCAT4 | c.1566G>T p.K522N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MIPOL1 | c.665A>T p.Q222L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC5B | c.5127G>A p.W1709* | Nonsense Mutation (SNP) | VAF 113/207 reads (55%) | called by muse, mutect2, varscan2
- MXI1 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- NDST3 | c.1295T>A p.V432D | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PRDM1 | c.2021T>A p.L674Q | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- RELN | c.3941G>C p.S1314T | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.4396del p.T1466Qfs*4 | Frame Shift Del (DEL) | VAF 74/537 reads (14%) | called by mutect2, pindel, varscan2
- SASH1 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFPQ | c.1179A>T p.Q393H | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SGPL1 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 56/106 reads (53%) | called by muse, mutect2, varscan2
- TMEM199 | c.460A>C p.I154L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TNRC6C | c.4325A>G p.K1442R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNXB | c.4663G>A p.A1555T (on ENST00000647633; = p.A1308T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- U2SURP | c.2020A>T p.I674F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- USP54 | c.3746G>A p.G1249D | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRA2 | c.1510C>T p.L504= | Silent (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- C7 | c.210A>C p.T70= | Silent (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- EML1 | c.2409C>T p.G803= | Silent (SNP) | VAF 26/388 reads (7%) | catalogued as rs768857775, COSV51748393; called by muse, mutect2
- GNL2 | c.1872A>T p.I624= | Silent (SNP) | VAF 120/253 reads (47%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.312C>G p.T104= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs752217879; called by muse, varscan2
- IGHV2-70 | c.276G>A p.K92= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs371562118; called by muse, varscan2
- IGLV3-27 | c.190C>T p.L64= | Silent (SNP) | VAF 114/116 reads (98%) | catalogued as rs561986283; called by muse, mutect2, varscan2
- KERA | c.189C>T p.L63= | Silent (SNP) | VAF 135/247 reads (55%) | called by muse, mutect2, varscan2
- NOP58 | c.49C>T p.L17= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1340695567; called by muse, mutect2
- PKHD1L1 | c.6879G>A p.V2293= | Silent (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- SPOCD1 | c.1188C>A p.G396= | Silent (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- SVIL | c.1662C>T p.P554= | Silent (SNP) | VAF 116/257 reads (45%) | catalogued as COSV63443881; called by muse, mutect2, varscan2
- SYNE2 | c.18315G>A p.S6105= | Silent (SNP) | VAF 165/333 reads (50%) | catalogued as rs202084149; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TRIM72 | c.894G>A p.A298= | Silent (SNP) | VAF 74/291 reads (25%) | catalogued as COSV59067110; called by muse, mutect2, varscan2
- TSGA10 | c.616T>C p.L206= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV61826371; called by muse, mutect2, varscan2
- ZNF639 | c.15T>A p.P5= | Silent (SNP) | VAF 106/326 reads (33%) | catalogued as rs372654154; called by muse, mutect2, varscan2
- ZNF706 | c.192G>A p.K64= | Silent (SNP) | VAF 59/303 reads (19%) | called by muse, mutect2, varscan2
- AC079612.1 | n.451T>C | RNA (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+5666G>T | Intron (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+5528C>A | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- AC244258.1 | n.592A>T | RNA (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- AGPAT4 | c.*1132_*1134del | 3'UTR (DEL) | VAF 46/85 reads (54%) | called by pindel, varscan2
- AMPD2 | c.*738C>T | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- ANAPC1P6 | n.364T>C | RNA (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- ANXA2R | c.-1078T>A | 5'UTR (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- AOX1 | c.1060-86A>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- BPI | c.*107C>T | 3'UTR (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- CAMKK2 | c.*2307C>T | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2
- CAMKV | c.303-55T>C | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- CATIP | c.922-94C>T | Intron (SNP) | VAF 35/66 reads (53%) | catalogued as COSV56822381; called by muse, mutect2, varscan2
- CD99L2 | c.130+1719G>T | Intron (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- CDR1 | chrX:140784536 A>T | 5'Flank (SNP) | VAF 246/658 reads (37%) | called by muse, mutect2, varscan2
- CNGB3 | c.*1708C>T | 3'UTR (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- CPAMD8 | c.628-52G>T | Intron (SNP) | VAF 57/267 reads (21%) | called by muse, mutect2, varscan2
- CTNNBIP1 | chr1:9850179 A>G | 3'Flank (SNP) | VAF 107/228 reads (47%) | called by muse, mutect2, varscan2
- CTSC | c.318+9004C>A | Intron (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- CXCL3 | c.-64G>C | 5'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- DCAF17 | c.*404A>T | 3'UTR (SNP) | VAF 80/174 reads (46%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*3929C>T | 3'UTR (SNP) | VAF 66/114 reads (58%) | called by muse, mutect2, varscan2
- DYSF | c.88+12671C>T | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- EDN3 | c.*65T>G | 3'UTR (SNP) | VAF 42/159 reads (26%) | catalogued as rs555946641; called by muse, mutect2, varscan2
- EGFR | c.3271+399A>C | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2
- ENPP1 | c.*2399del | 3'UTR (DEL) | VAF 36/87 reads (41%) | catalogued as rs1333869496; called by mutect2, varscan2
- EPB41L4A | c.1739+17A>T | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- FAM181B | c.*416A>C | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2
- FBXO32 | c.*1815C>T | 3'UTR (SNP) | VAF 69/142 reads (49%) | catalogued as rs184380621; called by muse, mutect2, varscan2
- FGFR3 | c.*1476G>A | 3'UTR (SNP) | VAF 24/108 reads (22%) | catalogued as CM084810, CM990597, COSV53411338; called by muse, mutect2, varscan2
- FGFR3 | chr4:1807526 G>C | 3'Flank (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- FLNA | c.6907+35G>C | Intron (SNP) | VAF 13/149 reads (9%) | called by muse, mutect2
- FNDC3B | c.*3C>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- GABRB3 | c.*4164A>T | 3'UTR (SNP) | VAF 93/160 reads (58%) | called by muse, mutect2, varscan2
- GATAD2B | c.*163C>T | 3'UTR (SNP) | VAF 43/202 reads (21%) | catalogued as rs1026118662, COSV64084427; called by muse, mutect2, varscan2
- GRK3 | c.*266T>C | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1031078411; called by muse, varscan2
- HELT | c.133-125A>G | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- HERPUD1 | c.-73A>T | 5'UTR (SNP) | VAF 88/213 reads (41%) | called by muse, mutect2, varscan2
- HGF | c.*2330G>T | 3'UTR (SNP) | VAF 89/158 reads (56%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*508T>G | 3'UTR (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899624 A>T | 3'Flank (SNP) | VAF 106/110 reads (96%) | catalogued as rs112327205; called by muse, mutect2, varscan2
- IGSF3 | c.*1918A>G | 3'UTR (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- IRAK3 | c.*4039T>C | 3'UTR (SNP) | VAF 33/52 reads (63%) | called by muse, mutect2, varscan2
- KCNC2 | c.*2771T>G | 3'UTR (SNP) | VAF 84/206 reads (41%) | catalogued as rs1472982433; called by muse, mutect2, varscan2
- KLC1 | c.1650+5836T>G | Intron (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- KMT2C | c.*1257A>T | 3'UTR (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- LOXL1 | c.-71G>A | 5'UTR (SNP) | VAF 7/72 reads (10%) | catalogued as rs909960506; called by muse, mutect2, varscan2
- LRRC19 | c.*604C>T | 3'UTR (SNP) | VAF 112/221 reads (51%) | catalogued as rs1033878871; called by muse, mutect2, varscan2
- MAN1A2 | c.*4181T>A | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- MAPK11 | c.-11C>G | 5'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100404608; called by muse, mutect2
- MLLT6 | c.*1372G>T | 3'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- MMP16 | c.*8502C>T | 3'UTR (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- MOGAT2 | c.650+73G>A | Intron (SNP) | VAF 55/295 reads (19%) | called by muse, mutect2, varscan2
- MPC2 | c.*1579T>G | 3'UTR (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.-27C>G | 5'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- NDUFV2P1 | n.148G>A | RNA (SNP) | VAF 10/35 reads (29%) | catalogued as rs947864117; called by muse, mutect2
- NUP153 | c.*22C>T | 3'UTR (SNP) | VAF 53/296 reads (18%) | called by muse, mutect2, varscan2
- NUP160 | chr11:47848485 G>C | 5'Flank (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- NUP58 | c.1435+1310C>A | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- PAX5 | c.*2588T>C | 3'UTR (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2
- PKNOX2 | c.*1457T>C | 3'UTR (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
- PPARGC1A | chr4:23890060 A>G | 5'Flank (SNP) | VAF 150/311 reads (48%) | called by muse, mutect2, varscan2
- RAVER2 | c.*940A>G | 3'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- RBBP9 | c.*174C>T | 3'UTR (SNP) | VAF 64/105 reads (61%) | called by muse, mutect2, varscan2
- RGS5 | c.*66T>A | 3'UTR (SNP) | VAF 149/567 reads (26%) | called by muse, mutect2, varscan2
- ROS1 | c.5366+693G>A | Intron (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- SLC24A4 | c.*2500G>T | 3'UTR (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- SLFN13 | c.*3225G>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SLITRK4 | chrX:143626085 C>A | 3'Flank (SNP) | VAF 78/140 reads (56%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143626359 A>G | 3'Flank (SNP) | VAF 68/109 reads (62%) | called by muse, mutect2, varscan2
- SMURF1 | c.*3005A>T | 3'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- SRPK2 | c.*1067T>G | 3'UTR (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- SSRP1 | c.1297-117C>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- TAGAP | c.148+19C>T | Intron (SNP) | VAF 83/165 reads (50%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2912C>T | RNA (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- TM4SF18 | c.*1926C>A | 3'UTR (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- TMEM47 | c.*1474A>C | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- TUB | c.*3704G>A | 3'UTR (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- TUBB2B | c.*256T>A | 3'UTR (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- UCHL5 | chr1:193059879 G>A | 5'Flank (SNP) | VAF 45/417 reads (11%) | catalogued as COSV100814669; called by muse, mutect2, varscan2
- USP8 | c.*175_*193del | 3'UTR (DEL) | VAF 40/362 reads (11%) | called by mutect2, pindel
- VPS37B | c.111+7506T>A | Intron (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2
- WDFY1 | c.*2609A>T | 3'UTR (SNP) | VAF 47/145 reads (32%) | called by muse, mutect2, varscan2
- XIST | n.7732A>T | RNA (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- XYLB | c.141-4485G>A | Intron (SNP) | VAF 41/843 reads (5%) | called by muse, mutect2
- ZBTB20 | c.*135T>G | 3'UTR (SNP) | VAF 8/66 reads (12%) | catalogued as rs1041921260; called by muse, mutect2
- ZNF483 | c.412+210T>G | Intron (SNP) | VAF 93/169 reads (55%) | called by muse, mutect2, varscan2
- ZNF75D | c.697-148C>T | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
